Somatic mutation profile of tumor specimen TCGA-KQ-A41R-01A (aliquot TCGA-KQ-A41R-01A-21D-A34U-08) from TCGA case TCGA-KQ-A41R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 80.4 years (29,351 days).
Specimen TCGA-KQ-A41R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70f77a8a-7ae7-4d5f-8231-23136d8a2121.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KQ-A41R-10G (Blood Derived Normal), aliquot TCGA-KQ-A41R-10G-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c839360a-36e5-41d0-b9ba-33579c459387

The open-access MAF lists 873 somatic variants for this specimen: 607 protein-altering or splice-affecting, 244 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 502, Silent 244, Nonsense Mutation 57, Frame Shift Del 16, Splice Site 14, Intron 11, Splice Region 7, In Frame Del 5, RNA 5, 5'UTR 4, Frame Shift Ins 3, Translation Start Site 2.

Variants (750 of 873; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs141798398, CM072935, COSV58687783, COSV58689693; ClinVar: uncertain significance; called by muse, mutect2
- ERCC2 | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55538701; called by muse, mutect2, varscan2
- PTEN | c.531T>G p.Y177* | Nonsense Mutation (SNP) | VAF 91/176 reads (52%) | hotspot (GDC flag); catalogued as rs878853012, COSV100909304, COSV64289866, COSV64296956; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATK | c.3598G>A p.E1200K (on ENST00000326724 / NM_001080395.3; = p.E1097K on NM_004920.2) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100353152; called by muse, mutect2, varscan2
- ABCA13 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.176); catalogued as COSV70032848; called by muse, mutect2, varscan2
- ABCA2 | c.7198G>C p.E2400Q (on ENST00000614293; = p.E2370Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as COSV55803037; called by muse, mutect2, varscan2
- ABCA6 | c.1277A>G p.E426G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779453616, COSV52640524; called by muse, mutect2, varscan2
- ACSL4 | c.950G>A p.G317D (on ENST00000340800 / NM_022977.2; = p.G276D on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61614904; called by muse, mutect2, varscan2
- ACTR2 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 79/117 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV53201697; called by muse, mutect2, varscan2
- ADAM30 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 93/140 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV65561446; called by muse, mutect2, varscan2
- ADAMTSL4 | c.3131T>C p.V1044A | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55001831; called by muse, mutect2
- ADCY7 | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745887234, COSV54268083; called by muse, mutect2, varscan2
- ADGRG4 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV54959940; called by muse, mutect2
- ADGRV1 | c.17147C>G p.T5716S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV67988452; called by muse, mutect2, varscan2
- AEBP2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV56864464; called by muse, mutect2, varscan2
- AFP | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as rs760793408, COSV56925745; called by muse, mutect2, varscan2
- AGAP6 | c.893A>T p.D298V (on ENST00000374056 / NM_001365867.1; = p.D321V on NM_001077665.2) | Missense Mutation (SNP) | VAF 165/447 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65017881; called by muse, mutect2, varscan2
- AGO2 | c.1798C>T p.H600Y | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55048959; called by muse, mutect2, varscan2
- AGO4 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64617317, COSV64617624; called by muse, mutect2, varscan2
- AGTPBP1 | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV61273330; called by muse, mutect2, varscan2
- AHNAK2 | c.2517G>C p.K839N | Missense Mutation (SNP) | VAF 156/493 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60919281; called by muse, mutect2, varscan2
- AHR | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV54124426; called by muse, mutect2, varscan2
- ALDH1A1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.441); catalogued as COSV52792247; called by muse, mutect2, varscan2
- ALDH1L2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as COSV51557116; called by muse, mutect2, varscan2
- ALOX12 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52350592; called by muse, mutect2, varscan2
- ALPK3 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.444); catalogued as COSV51935176, COSV99360603; called by muse, mutect2, varscan2
- AMER1 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as CM090023, COSV100366895; called by muse, mutect2, varscan2
- AMPD1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV62416815; called by muse, mutect2, varscan2
- AMZ2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100703125, COSV63083288; called by muse, mutect2, varscan2
- ANKRD37 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV52992015; called by muse, mutect2, varscan2
- ANO1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV60284939, COSV60286220; called by muse, mutect2, varscan2
- AP1B1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58019120; called by muse, varscan2
- AP3M1 | c.337T>G p.L113V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62331673; called by muse, mutect2, varscan2
- APCDD1 | c.989C>A p.S330* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100790006; called by muse, mutect2
- APIP | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53507467; called by muse, mutect2, varscan2
- ARFGEF2 | c.2227G>T p.D743Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64213205; called by muse, mutect2, varscan2
- ARHGAP32 | c.2715G>C p.M905I (on ENST00000310343 / NM_001378025.1; = p.M556I on NM_014715.4) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59850502; called by muse, mutect2
- ARHGEF40 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs113574695; called by muse, mutect2, varscan2
- ARID3C | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52407887; called by muse, mutect2, varscan2
- ARID5A | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs759800138, COSV62591342; called by muse, mutect2, varscan2
- ARL14 | c.479C>G p.T160R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV57900031; called by muse, varscan2
- ARL14 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1394056850, COSV57900042; called by muse, varscan2
- ARSB | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as COSV99365418; called by muse, mutect2, varscan2
- ASZ1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52913777; called by muse, mutect2, varscan2
- ATAD2 | c.3055C>T p.P1019S | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.891); catalogued as COSV54882713; called by muse, mutect2, varscan2
- ATAD5 | c.5219A>G p.D1740G | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV58975974; called by muse, mutect2, varscan2
- ATN1 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); catalogued as COSV63111752; called by muse, mutect2, varscan2
- ATP13A2 | c.1792C>G p.Q598E | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100454301, COSV58701510; called by muse, mutect2
- BAIAP3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs776493141, COSV60981215; called by muse, mutect2, varscan2
- BAIAP3 | c.2993T>C p.L998P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50104314; called by muse, mutect2
- BCL2L15 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV63643119; called by muse, mutect2, varscan2
- BCLAF1 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.356); catalogued as COSV62143377; called by muse, mutect2, varscan2
- BDH2 | c.700G>C p.G234R | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56478905; called by muse, mutect2, varscan2
- BICRA | c.2738G>T p.S913I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV67605252; called by muse, mutect2, varscan2
- BLOC1S2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.75); catalogued as COSV100559428; called by muse, mutect2, varscan2
- BMP1 | c.2440A>G p.K814E | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.309); catalogued as rs1396014404, COSV60531939; called by muse, mutect2, varscan2
- BTG2 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.142); catalogued as rs765070160, COSV51856506; called by muse, mutect2, varscan2
- BTK | c.1759A>T p.M587L | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as CM950175, COSV100437834; called by muse, mutect2
- BVES | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV58948540; called by muse, mutect2, varscan2
- C1orf116 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 25/39 reads (64%) | catalogued as COSV100847995; called by muse, mutect2, varscan2
- C4orf19 | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 198/485 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1424617040, COSV52649636; called by muse, mutect2, varscan2
- CACNA1D | c.5826C>G p.I1942M (on ENST00000350061 / NM_001128840.3; = p.I1962M on NM_000720.4) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV55452861; called by muse, mutect2, varscan2
- CACNA1S | c.4331C>T p.A1444V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100755269; called by muse, mutect2
- CALCRL | c.997A>C p.K333Q | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66475721; called by muse, mutect2, varscan2
- CAPN15 | c.263C>G p.P88R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV54837146; called by muse, mutect2, varscan2
- CAPRIN2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51833434; called by muse, mutect2, varscan2
- CARD6 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54566176; called by muse, mutect2, varscan2
- CARM1 | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.954); catalogued as COSV53404192; called by muse, mutect2
- CBARP | c.1204G>T p.A402S (on ENST00000382477; = p.A382S on NM_152769.3) | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53070053; called by muse, mutect2, varscan2
- CCDC117 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99968811, COSV99968942; called by muse, mutect2, varscan2
- CCDC14 | c.439G>A p.D147N (on ENST00000488653; = p.D99N on NM_022757.5) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV59945655; called by muse, mutect2, varscan2
- CCDC74A | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.363); catalogued as COSV99723866; called by mutect2, varscan2
- CCDC74B | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.595); catalogued as COSV100134667; called by muse, mutect2, varscan2
- CCDC90B | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.433); catalogued as COSV52624360; called by muse, mutect2, varscan2
- CCL14 | c.77C>G p.S26* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as rs1355977352; called by muse, mutect2, varscan2
- CCND3 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as COSV100026915; called by muse, mutect2
- CCR10 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52851721; called by muse, mutect2, varscan2
- CD14 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100117505, COSV57370949; called by muse, mutect2, varscan2
- CDC42BPG | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs147422193, COSV100712180; called by muse, mutect2, varscan2
- CDC45 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 95/138 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs1284753021, COSV54246380; called by muse, mutect2, varscan2
- CDC73 | c.264A>T p.R88S | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV66467952; called by muse, mutect2, varscan2
- CDK12 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV71001352, COSV71001754, COSV71002334; called by muse, mutect2, varscan2
- CELSR1 | c.8912C>T p.S2971F | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV53093123; called by muse, mutect2, varscan2
- CELSR1 | c.5923G>A p.D1975N | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV53093133; called by muse, mutect2, varscan2
- CENPE | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV54383275; called by muse, mutect2, varscan2
- CEP104 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV65518027; called by muse, mutect2, varscan2
- CEP131 | c.2257G>A p.E753K (on ENST00000269392 / NM_001319228.2; = p.E750K on NM_014984.4) | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763110139, COSV53956013; called by muse, mutect2, varscan2
- CEP250 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100699228, COSV61171245; called by muse, mutect2, varscan2
- CEP97 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV59125466; called by muse, mutect2, varscan2
- CHD7 | c.4670G>A p.R1557K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101418008, COSV101418384; called by muse, mutect2
- CHD9 | c.8642C>T p.S2881F (on ENST00000398510 / NM_001382353.1; = p.S2865F on NM_025134.7) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as COSV54612125, COSV54612424; called by muse, mutect2, varscan2
- CHML | c.679A>G p.R227G | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59365340; called by muse, mutect2, varscan2
- CILP | c.535G>C p.A179P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.66); catalogued as COSV56025429, COSV56028339; called by muse, mutect2, varscan2
- CKMT1B | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361072985, COSV100294656; called by muse, mutect2, varscan2
- CLEC16A | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68500383; called by muse, mutect2, varscan2
- CLN8 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58670884; called by muse, mutect2, varscan2
- CLU | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs746198403, COSV57067174; called by muse, mutect2, varscan2
- CLUH | c.3744C>T p.L1248= (on ENST00000435359; = p.L1287= on NM_015229.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/23 reads (43%) | catalogued as COSV70929245; called by muse, mutect2, varscan2
- CMTR1 | c.1315A>T p.N439Y | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65090723; called by muse, mutect2, varscan2
- CMYA5 | c.6235G>T p.V2079L | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV71406962; called by muse, mutect2, varscan2
- COASY | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV55899327; called by muse, mutect2, varscan2
- COG3 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV63073603; called by muse, mutect2, varscan2
- COL21A1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs780566383, COSV55168403, COSV99778371; called by muse, mutect2, varscan2
- COL5A3 | c.3103C>A p.P1035T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV53413326; called by muse, mutect2
- CPSF2 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs762100349, COSV54099052; called by muse, mutect2, varscan2
- CRB2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100749722; called by muse, mutect2, varscan2
- CRKL | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62882920; called by muse, mutect2, varscan2
- CRLF1 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV62260755; called by muse, mutect2, varscan2
- CRNKL1 | c.1399G>A p.G467S | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as COSV66106181; called by muse, mutect2, varscan2
- CT47A6 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 116/402 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.065); catalogued as rs749291393, COSV70031692; called by muse, varscan2
- CTNNA2 | c.2007G>A p.R669= | Splice Region (SNP) | VAF 18/52 reads (35%) | catalogued as rs761362452, COSV100561920, COSV58159897; called by muse, mutect2, varscan2
- CTPS2 | c.1389A>G p.I463M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.6); catalogued as rs762507057, COSV63723077; called by muse, mutect2, varscan2
- CTTNBP2 | c.4934C>G p.S1645* | Nonsense Mutation (SNP) | VAF 59/139 reads (42%) | catalogued as COSV99354634; called by muse, mutect2, varscan2
- CUBN | c.3660del p.D1221Ifs*16 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | catalogued as COSV64719371, COSV64723157; called by mutect2, pindel, varscan2
- CUTC | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV65081941; called by muse, mutect2
- CUX2 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.367); catalogued as rs760670696, COSV55639376; called by muse, mutect2, varscan2
- CWC22 | c.2333G>A p.R778K | Missense Mutation (SNP) | VAF 56/83 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV55429722; called by muse, mutect2, varscan2
- CWF19L2 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.314); catalogued as COSV56514911; called by muse, mutect2, varscan2
- CYBB | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as rs781797749, COSV66085714; called by muse, mutect2, varscan2
- CYHR1 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); catalogued as rs747604784, COSV56761703; called by muse, mutect2, varscan2
- DAGLB | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 77/129 reads (60%) | catalogued as COSV99766084; called by muse, mutect2, varscan2
- DCDC2 | c.923-1G>A p.X308_splice | Splice Site (SNP) | VAF 36/291 reads (12%) | catalogued as COSV65829191; called by muse, mutect2, varscan2
- DCTN4 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 28/43 reads (65%) | catalogued as COSV101437574; called by muse, mutect2, varscan2
- DCX | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57568266; called by muse, mutect2, varscan2
- DDX10 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59436565; called by muse, mutect2, varscan2
- DENND1A | c.1424T>C p.L475P | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV65327617; called by muse, mutect2, varscan2
- DENND5B | c.2207T>C p.V736A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60904153; called by muse, mutect2, varscan2
- DGKQ | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs370998016; called by muse, varscan2
- DHX33 | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV56579668; called by muse, mutect2
- DIDO1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56626362; called by muse, mutect2, varscan2
- DMBT1 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV57548411; called by muse, mutect2, varscan2
- DMBT1 | c.5678C>T p.S1893L (on ENST00000338354 / NM_001377530.1; = p.S1136L on NM_004406.3) | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.92); catalogued as COSV57548439; called by muse, mutect2, varscan2
- DMXL2 | c.7873C>T p.Q2625* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99198279; called by muse, mutect2, varscan2
- DNAH10 | c.4100G>A p.R1367K (on ENST00000409039; = p.R1306K on NM_207437.3) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV68996010; called by muse, mutect2, varscan2
- DNAH2 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV50016019; called by muse, mutect2, varscan2
- DNAH7 | c.11978C>T p.S3993F | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754480100, COSV56771294; called by muse, mutect2, varscan2
- DNAH9 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52335519; called by muse, mutect2
- DNAJC11 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53787937; called by muse, mutect2, varscan2
- DNASE2B | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101042128; called by muse, mutect2, varscan2
- DNMT3A | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767226511, COSV53045034, COSV53051884, COSV99258949; called by muse, mutect2, varscan2
- DOC2A | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV58751827; called by muse, mutect2, varscan2
- DOCK7 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV51996220, COSV52002182, COSV52011081; called by muse, mutect2, varscan2
- DOK5 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs749390006, COSV52818568; called by muse, mutect2, varscan2
- DPYS | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV59827080; called by muse, mutect2, varscan2
- DR1 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64725652; called by muse, mutect2, varscan2
- DST | c.8191G>A p.D2731N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV55022830; called by muse, mutect2, varscan2
- DST | c.3937C>T p.Q1313* (on ENST00000361203 / NM_001374722.1; = p.Q987* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99758985; called by muse, mutect2, varscan2
- DST | c.3419C>T p.S1140F (on ENST00000361203 / NM_001374722.1; = p.S814F on NM_001723.6) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs746870219, COSV55022868; called by muse, mutect2, varscan2
- DST | c.3188C>G p.S1063* (on ENST00000361203 / NM_001374722.1; = p.S737* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99758997; called by muse, mutect2
- DTL | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs146481751; called by muse, mutect2, varscan2
- DUOXA2 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.144); catalogued as COSV50993939; called by muse, mutect2, varscan2
- DUSP6 | c.870G>C p.L290F | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54379012, COSV99684174; called by muse, mutect2, varscan2
- DYNC1H1 | c.3913G>T p.E1305* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100794237, COSV100795266; called by muse, mutect2, varscan2
- DYRK1A | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.745); catalogued as COSV58707332; called by muse, mutect2, varscan2
- DYSF | c.2533G>A p.G845S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV50456949; called by muse, mutect2, varscan2
- E4F1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs890963695, COSV57039747; called by muse, mutect2, varscan2
- EBAG9 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61753259; called by muse, mutect2
- ECM2 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs13298061, COSV60741506; called by muse, mutect2, varscan2
- EDN2 | c.524G>A p.W175* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as rs745767820, COSV101006355; called by muse, mutect2, varscan2
- EFHB | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV55549621; called by muse, mutect2
- EIF2AK3 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs1049632455, COSV57549078; called by muse, mutect2, varscan2
- EIF4G1 | c.1929+2T>G p.X643_splice (on ENST00000346169 / NM_198241.3; = p.X447_splice on NM_004953.5) | Splice Site (SNP) | VAF 99/206 reads (48%) | catalogued as COSV59991887; called by muse, mutect2, varscan2
- EIF5 | c.447T>G p.S149R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV53685817; called by muse, mutect2, varscan2
- EML2 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV55601082; called by muse, mutect2, varscan2
- EPHA2 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64453674; called by muse, mutect2, varscan2
- ERBB4 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV53547108; called by muse, mutect2, varscan2
- ERGIC1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV67128458; called by muse, mutect2, varscan2
- ESRP1 | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1385406214, COSV64410677; called by muse, mutect2, varscan2
- ESS2 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV50082238, COSV99324015; called by muse, mutect2, varscan2
- EXOC6 | c.1531A>G p.T511A | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs569674088, COSV53326925; called by muse, mutect2, varscan2
- FAM187B | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV61201440; called by muse, mutect2, varscan2
- FAM43A | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV61673222; called by muse, mutect2, varscan2
- FAM71A | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99674855; called by muse, mutect2
- FAM76A | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1018915604, COSV50549091; called by muse, mutect2, varscan2
- FAM91A1 | c.1696-1G>C p.X566_splice | Splice Site (SNP) | VAF 25/188 reads (13%) | catalogued as COSV58237840; called by muse, mutect2, varscan2
- FASN | c.7291G>A p.E2431K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.402); catalogued as COSV60756833; called by muse, mutect2, varscan2
- FASN | c.4700A>G p.Y1567C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV60756856; called by muse, mutect2
- FAT2 | c.6321T>A p.Y2107* | Nonsense Mutation (SNP) | VAF 59/93 reads (63%) | catalogued as COSV99943860; called by muse, mutect2, varscan2
- FAT4 | c.3484G>A p.D1162N | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67890436; called by muse, mutect2, varscan2
- FBN1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs794728290, CM095634, COSV57320619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO27 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as rs745893570, COSV99494733; called by muse, mutect2, varscan2
- FGA | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV57397571; called by muse, mutect2
- FGD2 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as COSV51464348; called by muse, mutect2, varscan2
- FGD6 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 38/195 reads (19%) | catalogued as COSV100676758; called by muse, mutect2, varscan2
- FGF10 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.447); catalogued as COSV52936025, COSV99239955; called by muse, mutect2
- FITM1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV52824656; called by muse, mutect2, varscan2
- FLG | c.7595C>T p.S2532L | Missense Mutation (SNP) | VAF 63/575 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.497); catalogued as rs756739106, COSV64236669; called by muse, mutect2, varscan2
- FOLR3 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61530519; called by muse, mutect2
- FOXP1 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 51/82 reads (62%) | catalogued as COSV100562236; called by muse, mutect2, varscan2
- FOXR2 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV100189584; called by muse, mutect2, varscan2
- FRMD4A | c.1925G>A p.G642E | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV62266960; called by muse, mutect2, varscan2
- FSTL5 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 45/88 reads (51%) | catalogued as COSV100058735, COSV100059758; called by muse, mutect2, varscan2
- FZD1 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV55311807; called by muse, mutect2, varscan2
- GANC | c.1058-1G>A p.X353_splice | Splice Site (SNP) | VAF 23/43 reads (53%) | catalogued as COSV58809785; called by muse, mutect2, varscan2
- GAS2L1 | c.1564G>T p.E522* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as COSV53330840, COSV99329646; called by muse, mutect2, varscan2
- GASK1B | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.57); catalogued as COSV56708416; called by muse, mutect2, varscan2
- GFM2 | c.1760A>G p.H587R | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV54668730; called by muse, mutect2, varscan2
- GIGYF2 | c.2033C>T p.S678L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV65250850; called by muse, mutect2, varscan2
- GIMAP6 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV61033883; called by muse, mutect2, varscan2
- GLI2 | c.1732G>A p.V578I (on ENST00000361492 / NM_001374353.1; = p.V595I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as rs768557650, COSV58043749; called by muse, mutect2, varscan2
- GLMN | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV64860860, COSV64861176; called by muse, mutect2, varscan2
- GNAS | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55679718; called by muse, mutect2, varscan2
- GNL1 | c.475A>T p.I159F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV64835343; called by muse, mutect2, varscan2
- GOLGA4 | c.1041G>C p.Q347H | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV62711626; called by muse, mutect2
- GOLGA8A | c.1790T>C p.V597A (on ENST00000432566; = p.V569A on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs770429515, COSV62170127; called by muse, mutect2
- GON4L | c.2293G>T p.D765Y | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99675409; called by muse, mutect2, varscan2
- GOT1 | c.203A>C p.N68T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV65147513; called by muse, mutect2, varscan2
- GPD2 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV60094086; called by muse, mutect2, varscan2
- GPM6A | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54548237, COSV99702946; called by muse, mutect2, varscan2
- GPR146 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV52466507; called by muse, mutect2, varscan2
- GPR151 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV57038679; called by muse, mutect2, varscan2
- GPR158 | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66269203, COSV66273719; called by muse, mutect2, varscan2
- GPR176 | c.463T>C p.S155P | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54446018; called by muse, mutect2, varscan2
- GRID2 | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56223065; called by muse, mutect2, varscan2
- GUCY2F | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs372564035, COSV54304574; called by muse, mutect2, varscan2
- GYS2 | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV53924942; called by muse, mutect2, varscan2
- H1-0 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV50649319; called by muse, mutect2, varscan2
- H2BC9 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV55099027, COSV55099687, COSV99769055; called by muse, mutect2, varscan2
- HAUS8 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV53726548, COSV99505093; called by muse, mutect2, varscan2
- HBS1L | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774407298, COSV63200137; called by muse, mutect2
- HCAR3 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV63675353; called by muse, mutect2, varscan2
- HEATR5A | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as rs769992844, COSV66342514; called by muse, mutect2, varscan2
- HEATR5B | c.5032G>C p.E1678Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs1208135854, COSV51854640; called by muse, mutect2, varscan2
- HEATR5B | c.4900G>A p.D1634N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.517); catalogued as COSV51854648; called by muse, mutect2, varscan2
- HENMT1 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100898665, COSV64230358; called by muse, mutect2, varscan2
- HES1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.85); PolyPhen benign (0.165); catalogued as COSV51685062; called by muse, mutect2, varscan2
- HIVEP2 | c.3850G>C p.G1284R | Missense Mutation (SNP) | VAF 100/199 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.941); catalogued as rs549519966, COSV50020316; called by muse, mutect2, varscan2
- HLTF | c.2374C>A p.Q792K | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.043); catalogued as COSV59501761; called by muse, mutect2, varscan2
- HRNR | c.8086C>T p.Q2696* | Nonsense Mutation (SNP) | VAF 37/229 reads (16%) | catalogued as rs1315142895, COSV100913821; called by muse, mutect2, varscan2
- HSF2BP | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52357510; called by muse, mutect2, varscan2
- HSPA9 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as COSV99785638; called by muse, mutect2, varscan2
- HSPG2 | c.5967G>A p.W1989* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs985554091, COSV101021056; called by muse, mutect2, varscan2
- HUWE1 | c.5639G>C p.R1880P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53351686; called by muse, mutect2, varscan2
- IDO1 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as COSV53714929; called by muse, mutect2, varscan2
- IFRD1 | c.1042-1G>C p.X348_splice | Splice Site (SNP) | VAF 10/168 reads (6%) | catalogued as COSV50044461; called by muse, mutect2
- IFT52 | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1047392040, COSV65974699; called by muse, mutect2, varscan2
- IGBP1 | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60556669; called by muse, mutect2, varscan2
- IGDCC4 | c.3331G>A p.D1111N | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as COSV61536297, COSV61537768; called by muse, mutect2, varscan2
- IL27RA | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 45/108 reads (42%) | catalogued as COSV99652347; called by muse, mutect2, varscan2
- IL36A | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 27/50 reads (54%) | catalogued as rs1228773717, COSV52083169; called by muse, mutect2, varscan2
- IL4I1 | c.977C>A p.A326E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55579425; called by muse, mutect2, varscan2
- IL9R | c.851C>G p.T284S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV99730124; called by muse, mutect2, varscan2
- INTS4 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59019417; called by muse, mutect2, varscan2
- IRAG2 | c.3743T>C p.L1248P (on ENST00000636465; = p.L293P on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs751217489, COSV63139341; called by muse, mutect2, varscan2
- ITPR1 | c.5365G>A p.E1789K (on ENST00000354582; = p.E1734K on NM_002222.7) | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT tolerated (0.78); PolyPhen benign (0.204); catalogued as COSV56988024; called by muse, mutect2, varscan2
- ITPRID1 | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1264551879, COSV60076807; called by muse, mutect2, varscan2
- JCAD | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64760365; called by muse, mutect2, varscan2
- JPH4 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as COSV100436971; called by muse, mutect2, varscan2
- KAT6B | c.3882G>C p.E1294D | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.952); catalogued as COSV54749898; called by muse, mutect2, varscan2
- KAT7 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52015236; called by muse, mutect2, varscan2
- KCNA3 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV63902019; called by muse, mutect2, varscan2
- KCNA4 | c.1897G>A p.G633R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV60253590; called by muse, mutect2, varscan2
- KCNH1 | c.575C>G p.S192* | Nonsense Mutation (SNP) | VAF 28/100 reads (28%) | catalogued as COSV99656726, COSV99660788; called by muse, mutect2, varscan2
- KCNH5 | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100526006, COSV59763566; called by muse, mutect2, varscan2
- KCNH7 | c.1188C>G p.N396K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV59801276; called by muse, mutect2
- KCNK18 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100572115; called by muse, mutect2, varscan2
- KCTD20 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV54803662; called by muse, mutect2
- KCTD3 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52067956, COSV99378989; called by muse, mutect2, varscan2
- KDM3B | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100070106; called by muse, mutect2, varscan2
- KDM5A | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV66993716; called by muse, mutect2, varscan2
- KDM5B | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 111/152 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52509287; called by muse, mutect2, varscan2
- KDM6A | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.425); catalogued as rs1459042930, COSV65037779, COSV65039445, COSV65042219; called by muse, mutect2, varscan2
- KIAA0319L | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV57847184; called by muse, mutect2, varscan2
- KIAA1549L | c.3902C>T p.S1301L (on ENST00000321505; = p.S1598L on NM_012194.3) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448472720, COSV55776163; called by muse, mutect2, varscan2
- KIF1B | c.4543C>T p.R1515C (on ENST00000377086 / NM_001365952.1; = p.R1469C on NM_015074.3) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs774445070, COSV55810868; called by muse, mutect2, varscan2
- KIF20B | c.117T>G p.H39Q | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.035); catalogued as COSV53309756; called by muse, mutect2
- KLF4 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65929170; called by muse, mutect2, varscan2
- KLHL12 | c.646C>G p.P216A | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as COSV63042735, COSV63042799; called by muse, mutect2
- KLHL40 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV55135316; called by muse, mutect2, varscan2
- KLHL6 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.368); catalogued as COSV58067386; called by muse, mutect2, varscan2
- KMT2C | c.4346C>T p.S1449L | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV51456081, COSV51525109; called by muse, mutect2, varscan2
- KMT2D | c.13364G>A p.R4455H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372839823, COSV56463844; called by muse, mutect2, varscan2
- KRT27 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56972260; called by muse, mutect2, varscan2
- KRT6A | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV58106035; called by muse, mutect2, varscan2
- KRT75 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV52873125, COSV52873510, COSV99359378; called by mutect2, varscan2
- KRTAP9-8 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV54200274, COSV99565993; called by muse, mutect2, varscan2
- LAMA1 | c.4366C>T p.H1456Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV67539309; called by muse, mutect2, varscan2
- LAMA2 | c.2093T>C p.F698S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.287); catalogued as COSV70350687; called by muse, mutect2, varscan2
- LAMA3 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs964881956, COSV58071842; called by muse, mutect2, varscan2
- LAMA4 | c.1817+1G>T p.X606_splice (on ENST00000230538 / NM_001105206.3; = p.X599_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 37/75 reads (49%) | catalogued as COSV57899612; called by muse, mutect2, varscan2
- LAMA5 | c.8905G>A p.E2969K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99441730; called by muse, mutect2
- LAMB1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55966568; called by muse, mutect2, varscan2
- LARGE1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1361308052, COSV61659301, COSV61664541; called by muse, mutect2, varscan2
- LPCAT3 | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV54646351; called by muse, mutect2, varscan2
- LRCH2 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100406690, COSV57754857; called by muse, mutect2, varscan2
- LRP1 | c.8068G>A p.G2690S | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.115); catalogued as COSV54515975; called by muse, mutect2, varscan2
- LRRC14B | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0.013); catalogued as COSV57257340; called by muse, mutect2
- LRRC43 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV100336895; called by muse, mutect2, varscan2
- LRRIQ1 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV67813317; called by muse, mutect2, varscan2
- LRRK1 | c.2581C>T p.R861C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs981947042, COSV52616641, COSV99438370; called by muse, mutect2, varscan2
- LUZP4 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 26/107 reads (24%) | catalogued as COSV100904869; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 121/207 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV65419751; called by muse, mutect2, varscan2
- MACROD2 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV54005198; called by muse, mutect2, varscan2
- MAGEC1 | c.3143G>T p.W1048L | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV53575601; called by muse, mutect2, varscan2
- MAP3K5 | c.3697G>A p.D1233N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62890005; called by muse, mutect2, varscan2
- MAP4K4 | c.3292G>A p.D1098N (on ENST00000347699 / NM_001242559.2; = p.D1016N on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56333964; called by muse, mutect2, varscan2
- MARCHF10 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV60885704; called by muse, mutect2, varscan2
- MARCHF7 | c.1709G>A p.C570Y | Missense Mutation (SNP) | VAF 22/415 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52029414; called by muse, mutect2
- MCPH1 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57337903; called by muse, mutect2, varscan2
- MDN1 | c.6421G>A p.E2141K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV65523902; called by muse, mutect2, varscan2
- MECOM | c.2306C>T p.S769L (on ENST00000468789 / NM_001105078.4; = p.S957L on NM_004991.4) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV52967406; called by muse, mutect2, varscan2
- MERTK | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs868566811, COSV54931371; called by muse, mutect2, varscan2
- MIA2 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.216); catalogued as COSV54484382; called by muse, mutect2, varscan2
- MICAL2 | c.3989G>A p.R1330Q | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.702); catalogued as rs186750768; called by muse, mutect2, varscan2
- MINAR1 | c.2381G>A p.S794N | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.922); catalogued as COSV59584017; called by muse, mutect2, varscan2
- MINDY2 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57507332; called by muse, mutect2, varscan2
- MKNK2 | c.401A>T p.Y134F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV51733353; called by muse, mutect2, varscan2
- MMP27 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 105/192 reads (55%) | catalogued as COSV99498624; called by muse, mutect2, varscan2
- MNAT1 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.91); PolyPhen benign (0.109); catalogued as COSV54192208; called by muse, mutect2, varscan2
- MOB3A | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as rs1380744607, COSV63865925; called by muse, mutect2, varscan2
- MON2 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54809424; called by muse, mutect2, varscan2
- MON2 | c.5060C>T p.S1687F | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54809433; called by muse, mutect2, varscan2
- MRC2 | c.1461+2T>C p.X487_splice | Splice Site (SNP) | VAF 64/87 reads (74%) | catalogued as COSV57641243; called by muse, mutect2, varscan2
- MROH2B | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.137); catalogued as rs1427712030, COSV101270924, COSV68181885, COSV68186148; called by muse, mutect2, varscan2
- MRPL16 | c.206T>C p.L69S | Missense Mutation (SNP) | VAF 132/231 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55703427; called by muse, mutect2, varscan2
- MRPL45 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1043560556; called by muse, mutect2, varscan2
- MRPS14 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.109); catalogued as rs375534115; called by muse, mutect2, varscan2
- MRPS22 | c.214G>A p.E72K (on ENST00000310776 / NM_001363893.1; = p.E73K on NM_020191.4) | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV60350498; called by muse, mutect2, varscan2
- MTCL1 | c.1454G>A p.R485K (on ENST00000306329 / NM_001378206.1; = p.R125K on NM_015210.4) | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV60407718; called by muse, mutect2, varscan2
- MTMR7 | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1430160932, COSV51667674; called by muse, mutect2, varscan2
- MXRA5 | c.5003C>T p.S1668L | Missense Mutation (SNP) | VAF 117/219 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV54239856; called by muse, mutect2, varscan2
- MYBPC1 | c.206T>C p.V69A (on ENST00000550270 / NM_206820.2; = p.V94A on NM_002465.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as COSV100638224, COSV62254833; called by muse, mutect2
- MYCBP2 | c.9797G>A p.R3266K (on ENST00000357337; = p.R3304K on NM_015057.5) | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs751177125, COSV62025669; called by muse, mutect2, varscan2
- MYH1 | c.3917C>G p.S1306W | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV56851278, COSV56855512; called by muse, mutect2, varscan2
- NANOS3 | c.491C>T p.S164L (on ENST00000397555; = p.S183L on NM_001098622.2) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs775855231, COSV59249204; called by muse, mutect2, varscan2
- NARS2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1280481942, COSV55252931; called by muse, mutect2, varscan2
- NCOA3 | c.3958C>T p.Q1320* (on ENST00000371998 / NM_181659.3; = p.Q1316* on NM_006534.4) | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as rs1345876740, COSV100508028; called by muse, mutect2, varscan2
- NCR1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 33/179 reads (18%) | catalogued as COSV99401116; called by muse, mutect2, varscan2
- NDUFAF7 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV50017968; called by muse, mutect2, varscan2
- NEUROG2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV57637586, COSV57638299; called by muse, mutect2, varscan2
- NFATC1 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.231); catalogued as COSV99502313; called by muse, mutect2, varscan2
- NFE2L1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62583448; called by muse, mutect2, varscan2
- NIN | c.6151A>C p.K2051Q (on ENST00000382041 / NM_182946.1; = p.K1338Q on NM_016350.4) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV55395684; called by muse, mutect2, varscan2
- NKX6-1 | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV55685045; called by muse, mutect2, varscan2
- NLRC4 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 46/88 reads (52%) | catalogued as COSV100707482, COSV61591349; called by muse, mutect2, varscan2
- NLRP2 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV54756674; called by muse, mutect2, varscan2
- NOMO3 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV99530931; called by mutect2, varscan2
- NOS1 | c.2877C>G p.N959K | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.694); catalogued as COSV57615262; called by muse, mutect2, varscan2
- NOS2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs200678947; called by muse, mutect2, varscan2
- NPAS4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs781764783, COSV60650087; called by muse, mutect2, varscan2
- NR1I3 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747474209, COSV63468452; called by muse, mutect2, varscan2
- NR2F2 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs201527820, CM143723, COSV67683800; called by muse, mutect2, varscan2
- NRAP | c.3347T>A p.L1116Q (on ENST00000359988 / NM_001322945.2; = p.L1081Q on NM_006175.4) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63491822; called by muse, mutect2, varscan2
- NSD1 | c.7795T>G p.S2599A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV61778471; called by muse, mutect2, varscan2
- NT5C3A | c.585C>G p.F195L (on ENST00000610140 / NM_001374335.1; = p.F161L on NM_016489.13) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.99); catalogued as COSV54238932; called by muse, mutect2, varscan2
- NTN4 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs781059917, COSV59221007; called by muse, mutect2, varscan2
- NUDC | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs956598607, COSV100345694; called by muse, mutect2
- NUDCD1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 174/215 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV53458084; called by muse, mutect2, varscan2
- NUDT12 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.085); catalogued as rs1390244385, COSV50091384; called by muse, mutect2, varscan2
- NUTF2 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as COSV99534564; called by muse, mutect2, varscan2
- NXN | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV61097671; called by muse, mutect2, varscan2
- OFD1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.213); catalogued as COSV60796763; called by muse, mutect2, varscan2
- OR2T12 | c.923A>C p.N308T | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58778134; called by muse, mutect2, varscan2
- OR6S1 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV57838511; called by muse, mutect2, varscan2
- OR7D4 | c.409A>C p.N137H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58071947; called by muse, mutect2, varscan2
- OSBPL3 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57658297; called by muse, mutect2, varscan2
- OSBPL7 | c.2298G>A p.R766= | Splice Region (SNP) | VAF 12/138 reads (9%) | catalogued as rs946338557, COSV50110349; called by muse, mutect2
- OTOGL | c.6109C>T p.Q2037* (on ENST00000547103; = p.Q2028* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100087723; called by muse, mutect2
- PA2G4 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV57568507; called by muse, mutect2, varscan2
- PALB2 | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV55166597; called by muse, mutect2, varscan2
- PARN | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58367440; called by muse, mutect2, varscan2
- PARP4 | c.3491A>T p.K1164I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV67962755; called by muse, mutect2, varscan2
- PCBP1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.156); catalogued as COSV57851265; called by muse, mutect2, varscan2
- PCBP3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs374895484; called by muse, mutect2, varscan2
- PCDH1 | c.1295G>A p.C432Y | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54615597; called by muse, mutect2, varscan2
- PCDHB5 | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50656786; called by muse, mutect2, varscan2
- PCDHGB4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV54049336, COSV99544543; called by muse, mutect2, varscan2
- PCDHGB4 | c.1557C>A p.D519E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53973734; called by muse, mutect2, varscan2
- PCLO | c.9020A>T p.Y3007F | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100436414; called by muse, mutect2
- PDGFD | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56382498, COSV56382644; called by muse, mutect2, varscan2
- PEAK1 | c.2356T>G p.S786A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV56938245; called by muse, mutect2, varscan2
- PGAP4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751492491, COSV66387897, COSV66388361; called by muse, mutect2, varscan2
- PI4K2B | c.461C>G p.P154R | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53511908; called by muse, mutect2, varscan2
- PIP5K1B | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV55250975; called by muse, mutect2, varscan2
- PITX3 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64174623; called by muse, mutect2, varscan2
- PIWIL2 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs768769441, COSV63251525; called by muse, mutect2, varscan2
- PKD1L1 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV56969498, COSV99221636; called by muse, mutect2, varscan2
- PKP4 | c.3286A>T p.S1096C | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV61579141; called by muse, mutect2, varscan2
- PLCB2 | c.307T>C p.S103P | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.869); catalogued as COSV53034972; called by muse, mutect2, varscan2
- PLCH1 | c.2644-1G>C p.X882_splice (on ENST00000340059 / NM_001130960.2; = p.X874_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/33 reads (48%) | catalogued as rs755420365, COSV100395302, COSV58202026; called by muse, mutect2, varscan2
- PLEKHA7 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV63047735; called by muse, mutect2, varscan2
- PMFBP1 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 95/186 reads (51%) | catalogued as COSV52820416; called by muse, mutect2, varscan2
- PNMA1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.201); catalogued as COSV54095825; called by muse, mutect2, varscan2
- POLA1 | c.4132A>G p.T1378A | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.174); catalogued as COSV66887824; called by muse, mutect2, varscan2
- POLR1A | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV55694992; called by muse, mutect2, varscan2
- POLR3A | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64931330; called by muse, mutect2, varscan2
- PPHLN1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs1565922703, COSV56732811; called by muse, mutect2, varscan2
- PPL | c.3951G>C p.E1317D | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV52166981, COSV52169408; called by muse, mutect2, varscan2
- PPP1R13L | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV62907934; called by muse, mutect2, varscan2
- PPP1R13L | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV62908892; called by muse, mutect2, varscan2
- PRDX5 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs1063141, COSV99134827; called by muse, varscan2
- PREPL | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53217550; called by muse, varscan2
- PRKCQ | c.1855G>C p.E619Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.91); catalogued as COSV54113548; called by muse, mutect2, varscan2
- PRPF8 | c.5267C>T p.S1756F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59264614; called by muse, mutect2, varscan2
- PRPH2 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57837640; called by muse, mutect2, varscan2
- PSMA5 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54748997; called by muse, mutect2, varscan2
- PSMA6 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54838105; called by muse, mutect2, varscan2
- PSME4 | c.5240T>A p.V1747E | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.026); catalogued as COSV66365928; called by muse, mutect2, varscan2
- PTGER2 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.095); catalogued as COSV55419225; called by muse, mutect2, varscan2
- PTK2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61787797; called by muse, mutect2, varscan2
- PTOV1 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55588718; called by muse, mutect2, varscan2
- PTPRH | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as COSV54746899; called by muse, mutect2, varscan2
- PTPRS | c.2992C>T p.Q998* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as rs1379393228, COSV99511983; called by muse, mutect2, varscan2
- PTPRZ1 | c.3313C>G p.H1105D | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV66434656, COSV66439862; called by muse, mutect2, varscan2
- RAMP3 | c.188T>A p.I63N | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54246036; called by muse, mutect2, varscan2
- RAPH1 | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55585859; called by muse, mutect2, varscan2
- RASA1 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM083066, COSV57195534, COSV57195581, COSV57197740; called by muse, mutect2, varscan2
- RASA3 | c.1916C>A p.S639Y | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100481093; called by muse, mutect2, varscan2
- RBBP6 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV60506165; called by muse, mutect2, varscan2
- RBM10 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV61309324; called by muse, mutect2
- RBM42 | c.684G>T p.L228= | Splice Region (SNP) | VAF 20/126 reads (16%) | catalogued as COSV52898043; called by muse, mutect2, varscan2
- RC3H1 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV51204290, COSV51212997; called by muse, mutect2, varscan2
- RCOR1 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51769317, COSV51772588; called by muse, mutect2, varscan2
- RELN | c.9736A>G p.I3246V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59012101; called by muse, mutect2, varscan2
- RGMA | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755157637, COSV61233411; called by muse, mutect2
- RHOB | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 104/163 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV55355253; called by muse, mutect2, varscan2
- RIMS2 | c.4561-1G>C p.X1521_splice (on ENST00000666250 / NM_001348490.2; = p.X1092_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 59/184 reads (32%) | catalogued as COSV51694013; called by muse, mutect2, varscan2
- RNASEH2C | c.448T>G p.W150G | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57729971; called by muse, mutect2, varscan2
- RNF103 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 130/229 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.453); catalogued as COSV52895844; called by muse, mutect2, varscan2
- RNF181 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs767430246, COSV57818170; called by muse, mutect2, varscan2
- RP1 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV55119765, COSV55127154; called by muse, mutect2, varscan2
- RPS8 | c.538G>C p.G180R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63234471; called by muse, mutect2, varscan2
- RRAS | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1428526675, COSV55868687; called by muse, mutect2, varscan2
- RREB1 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | catalogued as COSV58565678; called by muse, mutect2, varscan2
- RRP12 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100213396; called by muse, mutect2
- RTN4R | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50381666; called by muse, mutect2, varscan2
- RTTN | c.4315C>T p.L1439F | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as rs1485071837, COSV55347347; called by mutect2, varscan2
- RXRA | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100709343; called by muse, mutect2, varscan2
- RYR1 | c.6726C>G p.I2242M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771658147, COSV62101384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100A13 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as COSV52680336; called by muse, mutect2, varscan2
- SALL1 | c.1936G>C p.A646P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.261); catalogued as COSV51759611; called by muse, mutect2, varscan2
- SATL1 | c.220A>G p.I74V (on ENST00000395409; = p.I261V on NM_001012980.2) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV60577152; called by muse, mutect2, varscan2
- SBF2 | c.3634C>T p.Q1212* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99815351; called by muse, mutect2, varscan2
- SBNO2 | c.2514C>T p.F838= | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as rs1256037130, COSV100684914; called by muse, varscan2
- SCARF2 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV56732877; called by muse, mutect2, varscan2
- SCN2A | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 74/107 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51831451, COSV51846091; called by muse, mutect2, varscan2
- SCYL1 | c.1071G>A p.M357I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV54213580; called by muse, mutect2, varscan2
- SCYL2 | c.2203G>C p.V735L | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV62569396; called by muse, mutect2
- SCYL3 | c.1448A>T p.D483V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV53680025; called by muse, mutect2, varscan2
- SDHD | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as CM077225, COSV54778804; called by muse, mutect2, varscan2
- SDHD | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as COSV54778810; called by muse, mutect2, varscan2
- SEMA3C | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99543631; called by muse, mutect2, varscan2
- SEMA4D | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141440756; called by muse, mutect2, varscan2
- SEMG2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.175); catalogued as COSV65647612; called by muse, mutect2, varscan2
- SERGEF | c.1076A>G p.N359S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750912928, COSV56384666; called by muse, mutect2, varscan2
- SETD5 | c.3133G>A p.G1045S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.074); catalogued as COSV56713273; called by muse, mutect2, varscan2
- SH3GL1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV53658107; called by muse, mutect2, varscan2
- SIPA1L1 | c.5383G>A p.E1795K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62171179, COSV62172078; called by muse, mutect2, varscan2
- SIRPB1 | c.325A>T p.N109Y | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53539414; called by muse, mutect2
- SIRPB2 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV63124265; called by muse, mutect2, varscan2
- SLC1A6 | c.1584G>C p.E528D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV55671483; called by muse, mutect2, varscan2
- SLC25A25 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV66091311; called by muse, mutect2, varscan2
- SLC26A3 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100385264, COSV100385340; called by muse, mutect2, varscan2
- SLC28A3 | c.82A>G p.N28D | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV66153887; called by muse, mutect2, varscan2
- SLC35C1 | c.698A>G p.Y233C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV58480270; called by muse, mutect2, varscan2
- SLC38A9 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV59424496; called by muse, mutect2, varscan2
- SLC4A10 | c.1967A>G p.H656R (on ENST00000446997 / NM_001354461.2; = p.H626R on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.362); catalogued as COSV99765313; called by muse, mutect2
- SLC8A2 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV52639851, COSV52640614; called by muse, mutect2, varscan2
- SLC9A4 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs146351319, COSV54835669; called by muse, mutect2, varscan2
- SMARCB1 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV53156915; called by muse, mutect2, varscan2
- SMC1B | c.3221C>G p.S1074* | Nonsense Mutation (SNP) | VAF 39/79 reads (49%) | catalogued as COSV100663439; called by muse, mutect2, varscan2
- SMC1B | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100663042, COSV62530821; called by muse, mutect2, varscan2
- SMG7 | c.1171_1184del p.P391Sfs*4 | Frame Shift Del (DEL) | VAF 38/65 reads (58%) | catalogued as COSV61632346; called by mutect2, pindel, varscan2
- SNTG1 | c.1383G>T p.Q461H | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.459); catalogued as COSV52424658, COSV52442598; called by muse, mutect2, varscan2
- SNX17 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs762148517, COSV52008599; called by muse, mutect2, varscan2
- SOCS5 | c.962A>T p.N321I | Missense Mutation (SNP) | VAF 97/142 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60605394; called by muse, mutect2, varscan2
- SOCS7 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs1228430965; called by muse, mutect2, varscan2
- SPART | c.1482G>C p.L494= | Splice Region (SNP) | VAF 39/98 reads (40%) | catalogued as COSV62086420; called by muse, mutect2, varscan2
- SPATA5 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99916174; called by muse, mutect2
- SPECC1L | c.2920C>A p.P974T | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV58659413; called by muse, mutect2, varscan2
- SPIDR | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 78/135 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52380748, COSV99854774; called by muse, mutect2, varscan2
- SPN | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as rs373798010, COSV64070645; called by muse, varscan2
- SPNS2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); catalogued as COSV54599215; called by muse, mutect2, varscan2
- SRF | c.731C>G p.T244R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54839120; called by muse, mutect2, varscan2
- SRP68 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 176/235 reads (75%) | SIFT tolerated (0.54); PolyPhen benign (0.114); catalogued as COSV57163278; called by muse, mutect2, varscan2
- SRRM2 | c.4441G>A p.D1481N | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV57075612; called by muse, mutect2, varscan2
- SRSF8 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.265); catalogued as COSV71665558, COSV71665599; called by muse, mutect2, varscan2
- SSB | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV53627006; called by muse, mutect2, varscan2
- STAG2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 133/284 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54363081; called by muse, mutect2, varscan2
- SUCLG2 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV56207860; called by muse, mutect2, varscan2
- SULF1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV52685215; called by muse, mutect2, varscan2
- SULT1C3 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61253404; called by muse, mutect2, varscan2
- SULT1C3 | c.473T>A p.M158K | Missense Mutation (SNP) | VAF 74/125 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV61253415; called by muse, mutect2, varscan2
- SUMF2 | c.467G>A p.R156Q (on ENST00000652303; = p.R137Q on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs200947325, COSV51917012; called by muse, varscan2
- SUSD1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62584343; called by muse, mutect2
- SYBU | c.35G>C p.R12T (on ENST00000276646 / NM_001099754.2; = p.R11T on NM_017786.6) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV52620009; called by muse, mutect2, varscan2
- SYCP2 | c.4429G>A p.D1477N | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as rs769675463, COSV62769496; called by muse, mutect2, varscan2
- TACC2 | c.4690G>A p.A1564T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV57753857; called by muse, mutect2, varscan2
- TAS2R13 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV66831734; called by muse, mutect2, varscan2
- TAS2R30 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1387574872, COSV67857632; called by muse, mutect2, varscan2
- TBC1D20 | c.342G>C p.M114I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.487); catalogued as COSV100830599; called by muse, mutect2
- TBC1D9B | c.3085G>A p.E1029K (on ENST00000356834 / NM_198868.3; = p.E1012K on NM_015043.4) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV62282436; called by muse, mutect2, varscan2
- TBX15 | c.1079C>T p.S360L (on ENST00000369429 / NM_001330677.2; = p.S254L on NM_152380.3) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.492); catalogued as rs1313804216, COSV52867418; called by muse, mutect2, varscan2
- TBX15 | c.824C>T p.T275I (on ENST00000369429 / NM_001330677.2; = p.T169I on NM_152380.3) | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52872781; called by muse, mutect2, varscan2
- TBX19 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 26/178 reads (15%) | catalogued as COSV100892395; called by muse, mutect2, varscan2
- TCF7L2 | c.1382C>G p.P461R (on ENST00000355995 / NM_001367943.1; = p.P438R on NM_030756.5) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV53342674; called by muse, mutect2, varscan2
- TECTB | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.137); catalogued as COSV65595704; called by muse, mutect2, varscan2
- TENM1 | c.6374T>C p.I2125T | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1569528426, COSV64435295; called by muse, mutect2, varscan2
- TENM1 | c.1712G>C p.G571A | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64435298; called by muse, mutect2, varscan2
- TENM3 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV101305502, COSV69311877; called by muse, mutect2, varscan2
- TERT | c.2557C>G p.L853V | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV57222187; called by muse, varscan2
- TEX11 | c.2659G>A p.E887K (on ENST00000344304; = p.E872K on NM_031276.3) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs374367768, COSV60231914; called by muse, mutect2
- TGOLN2 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 739/1244 reads (59%) | SIFT tolerated (1); PolyPhen possibly damaging (0.813); catalogued as rs772750550, COSV56405330; called by muse, mutect2, varscan2
- THBD | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV101001914; called by muse, mutect2
- TIGD7 | c.1221A>C p.E407D | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV51916309; called by muse, mutect2
- TJP3 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV99516123; called by muse, mutect2, varscan2
- TKTL1 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV54213581; called by muse, mutect2, varscan2
- TLCD4-RWDD3 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 55/105 reads (52%) | PolyPhen benign (0.003); catalogued as COSV55721596, COSV55722281; called by muse, mutect2, varscan2
- TMED4 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV56942098; called by muse, mutect2, varscan2
- TMED5 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV58144750; called by muse, mutect2, varscan2
- TMEM141 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51567249; called by muse, mutect2, varscan2
- TMEM220 | c.319T>C p.W107R | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59379612; called by muse, mutect2, varscan2
- TMEM69 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV63432937; called by muse, mutect2, varscan2
- TMOD2 | c.625-1G>A p.X209_splice | Splice Site (SNP) | VAF 45/89 reads (51%) | catalogued as COSV51045000; called by muse, mutect2, varscan2
- TNFSF18 | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 28/37 reads (76%) | catalogued as COSV99513872; called by muse, mutect2, varscan2
- TNIK | c.2555A>G p.D852G | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV52686270; called by muse, mutect2, varscan2
- TOX2 | c.605C>T p.P202L (on ENST00000358131 / NM_001098798.2; = p.P151L on NM_032883.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1279388843, COSV57883191; called by muse, mutect2, varscan2
- TRAPPC10 | c.2926G>A p.D976N | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV52378655; called by muse, mutect2, varscan2
- TRH | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376108768; called by muse, mutect2, varscan2
- TRIM14 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs570888057, COSV99271460; called by muse, varscan2
- TRIM25 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs1165384134, COSV57544663; called by muse, mutect2, varscan2
- TRPM2 | c.3041C>T p.T1014M | Missense Mutation (SNP) | VAF 116/295 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs1408883225, COSV55971843; called by muse, mutect2, varscan2
- TRPM3 | c.275G>T p.G92V (on ENST00000357533 / NM_001366142.2; = p.G61V on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62471736; called by muse, mutect2, varscan2
- TRPS1 | c.1678A>G p.T560A (on ENST00000220888 / NM_001330599.2; = p.T573A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); catalogued as COSV55269423; called by mutect2, varscan2
- TRPS1 | c.1568A>G p.Y523C (on ENST00000220888 / NM_001330599.2; = p.Y536C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs749022707, COSV55248089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRRAP | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1554407969, COSV100722806; called by muse, mutect2, varscan2
- TTI1 | c.2362G>C p.E788Q | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV65062071; called by muse, mutect2, varscan2
- TUBGCP2 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs768896554, COSV53306270; called by muse, mutect2, varscan2
- TUBGCP5 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 48/95 reads (51%) | catalogued as rs369588518; called by muse, mutect2, varscan2
- UBR1 | c.509G>C p.R170T | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV51932031; called by muse, mutect2, varscan2
- UBXN2A | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58336944; called by muse, mutect2, varscan2
- UGT2B11 | c.1532T>C p.F511S | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV71423561, COSV71424278; called by muse, mutect2, varscan2
- UGT2B7 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV59444034; called by muse, mutect2, varscan2
- UNC13D | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52885526; called by muse, mutect2, varscan2
- UPF1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV53198044; called by muse, mutect2, varscan2
- USP31 | c.2078G>A p.R693K | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as COSV54853749; called by muse, mutect2, varscan2
- USPL1 | c.1113-1G>A p.X371_splice | Splice Site (SNP) | VAF 40/82 reads (49%) | catalogued as COSV55000562; called by muse, mutect2, varscan2
- UTP20 | c.7399C>T p.H2467Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1047284531, COSV55379638; called by muse, mutect2, varscan2
- VAC14 | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99934972; called by muse, mutect2, varscan2
- VEGFC | c.1072T>C p.C358R | Missense Mutation (SNP) | VAF 158/290 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54600406; called by muse, mutect2, varscan2
- VEPH1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as rs749997490, COSV62877570; called by muse, mutect2, varscan2
- VEZF1 | c.1274G>A p.R425K | Missense Mutation (SNP) | VAF 171/224 reads (76%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.745); catalogued as COSV51969231, COSV51969663; called by muse, mutect2, varscan2
- VILL | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.362); catalogued as COSV52184340; called by muse, mutect2
- VPS13D | c.13084A>C p.N4362H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50649510; called by muse, mutect2, varscan2
- VPS37B | c.57C>G p.N19K | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.118); catalogued as COSV57359769, COSV57360706; called by muse, mutect2, varscan2
- WASF2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs775407600, COSV71004909, COSV71005161; called by muse, mutect2, varscan2
- WDHD1 | c.696C>A p.T232= | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100864445; called by muse, mutect2
- WDR20 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs759947707, COSV54473288; called by muse, mutect2, varscan2
- WDR41 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56999275; called by muse, mutect2, varscan2
- XCL2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1383550599, COSV63194450; called by muse, mutect2, varscan2
- XRN1 | c.2132T>G p.L711R | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53813913; called by muse, mutect2, varscan2
- YLPM1 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99461012; called by muse, mutect2
- YME1L1 | c.1965G>C p.M655I (on ENST00000326799 / NM_139312.3; = p.M598I on NM_014263.4) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58760208; called by muse, mutect2, varscan2
- YPEL1 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV58607152; called by muse, mutect2, varscan2
- YY1 | c.1178A>G p.K393R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.718); catalogued as COSV51763100; called by muse, mutect2, varscan2
- ZBTB43 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100991450; called by muse, mutect2, varscan2
- ZEB2 | c.3166C>T p.Q1056* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100356641; called by muse, mutect2, varscan2
- ZFAT | c.3449C>T p.S1150L | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773594015, COSV64736135; called by muse, mutect2, varscan2
- ZFR | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 83/125 reads (66%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV54054778; called by muse, mutect2, varscan2
- ZHX1 | c.1459C>G p.Q487E | Missense Mutation (SNP) | VAF 87/468 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV52877460; called by muse, mutect2, varscan2
- ZMAT1 | c.1619A>T p.K540M | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65659001; called by muse, mutect2, varscan2
- ZMYM3 | c.1663G>C p.D555H | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.747); catalogued as rs1352706375, COSV58738774; called by muse, mutect2, varscan2
- ZNF207 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV58300703; called by muse, mutect2, varscan2
- ZNF426 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV53469665; called by muse, mutect2, varscan2
- ZNF440 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as COSV58371550, COSV58371557; called by muse, mutect2, varscan2
- ZNF543 | c.753_764del p.E252_Y255del | In Frame Del (DEL) | VAF 25/74 reads (34%) | catalogued as COSV58628006; called by mutect2, pindel, varscan2
- ZNF584 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs200679930; called by muse, mutect2, varscan2
- ZNF616 | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57511769; called by muse, mutect2, varscan2
- ZNF630 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 60/92 reads (65%) | catalogued as COSV99332535; called by muse, mutect2, varscan2
- ZNF638 | c.5753-2A>G p.X1918_splice | Splice Site (SNP) | VAF 127/197 reads (64%) | catalogued as COSV52490462; called by muse, mutect2, varscan2
- ZNF648 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs991256332, COSV60571583; called by muse, mutect2, varscan2
- ZNF665 | c.1723A>C p.T575P (on ENST00000600412; = p.T640P on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.206); catalogued as COSV67215889; called by muse, mutect2, varscan2
- ZNF701 | c.1192G>A p.D398N (on ENST00000301093; = p.D332N on NM_018260.3) | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV56525296; called by muse, mutect2, varscan2
- ZNF711 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV52155994; called by muse, mutect2, varscan2
- ZP3 | c.1169T>C p.L390P (on ENST00000394857 / NM_001110354.2; = p.L339P on NM_007155.6) | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100334663; called by muse, mutect2, varscan2
- ZZZ3 | c.2101A>T p.K701* | Nonsense Mutation (SNP) | VAF 38/86 reads (44%) | catalogued as COSV100890419; called by muse, mutect2, varscan2
- ACACA | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ATP2B1 | c.2759_2789del p.N920Rfs*12 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | called by mutect2, pindel
- CLPTM1L | c.1057_1072del p.A353Pfs*7 | Frame Shift Del (DEL) | VAF 28/152 reads (18%) | called by mutect2, pindel, varscan2
- FNDC1 | c.5375_5394del p.Y1792Cfs*4 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- FRMD4A | c.488del p.L163* | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- H2AC12 | c.-4_5del | Translation Start Site (DEL) | VAF 16/166 reads (10%) | called by mutect2, pindel
- HOXA9 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- HOXD8 | c.303_325del p.A102Pfs*32 | Frame Shift Del (DEL) | VAF 22/31 reads (71%) | called by mutect2, pindel, varscan2
- IGHG2 | c.322_331+7del p.X108_splice | Splice Site (DEL) | VAF 30/129 reads (23%) | called by mutect2, pindel, varscan2
- IGKV4-1 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- KDM5A | c.4918dup p.C1640Lfs*10 | Frame Shift Ins (INS) | VAF 47/123 reads (38%) | called by mutect2, pindel, varscan2
- KRT13 | c.401_402dup p.K135* | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | called by mutect2, pindel, varscan2
- KRTAP5-10 | c.307_308insCTGTGGCTCCTGTGGGGGCTCCAAGGGGA p.G103Afs*124 | Frame Shift Ins (INS) | VAF 26/82 reads (32%) | called by muse*, mutect2, varscan2*
- LHX1 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MAST2 | c.3229_3274del p.H1077Gfs*10 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel
- MGRN1 | c.955+2_955+3del p.X319_splice | Splice Site (DEL) | VAF 4/41 reads (10%) | called by pindel, varscan2
- MYO1E | c.3120_3122del p.G1041del | In Frame Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- NCAPG2 | c.3018_3033del p.V1007Sfs*8 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | called by mutect2, pindel, varscan2
- NEK11 | c.974_985del p.I325_Q328del | In Frame Del (DEL) | VAF 69/232 reads (30%) | called by mutect2, pindel, varscan2
- PREX2 | c.4261del p.R1421Efs*13 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- RIF1 | c.1048_1069del p.G350Lfs*8 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- RPUSD2 | c.68_73dup p.S23_F24dup | In Frame Ins (INS) | VAF 20/45 reads (44%) | called by mutect2, varscan2
- RRAGA | c.891_899del p.F297_K299del | In Frame Del (DEL) | VAF 41/90 reads (46%) | called by mutect2, pindel, varscan2
- RYR1 | c.9258_9259del p.E3086Dfs*69 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | called by pindel, varscan2
- SYNJ1 | c.199_213del p.E67_M71del | In Frame Del (DEL) | VAF 27/89 reads (30%) | called by mutect2, pindel, varscan2
- THBS2 | c.1242del p.C415Afs*13 | Frame Shift Del (DEL) | VAF 30/54 reads (56%) | called by mutect2, pindel, varscan2
- TRAV21 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TRMT112 | c.284_303del p.E95Gfs*19 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2467C>T p.Q823* | Nonsense Mutation (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- ZNF254 | c.1644_1656del p.C548* | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- ZNF365 | c.857del p.E286Gfs*36 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- ABCA9 | c.2907C>T p.H969= | Silent (SNP) | VAF 20/173 reads (12%) | catalogued as COSV60626909; called by muse, mutect2, varscan2
- ACBD4 | c.84G>A p.K28= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100416283; called by muse, mutect2
- ACBD6 | c.66G>A p.G22= | Silent (SNP) | VAF 33/48 reads (69%) | catalogued as COSV62574353; called by muse, mutect2, varscan2
- ADAM9 | c.225A>G p.K75= | Silent (SNP) | VAF 83/147 reads (56%) | catalogued as COSV65960907; called by muse, mutect2, varscan2
- ADAMTSL3 | c.657C>T p.V219= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV54454671; called by muse, mutect2, varscan2
- ADRB2 | c.585G>A p.T195= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV60005763; called by muse, mutect2, varscan2
- AFTPH | c.450C>T p.F150= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV53219189; called by muse, mutect2, varscan2
- AGAP3 | c.1083C>T p.I361= (on ENST00000622464; = p.I397= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs753777750, COSV58995044; called by muse, mutect2, varscan2
- ALDOC | c.172C>T p.L58= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs780045497, COSV52025136; called by muse, mutect2, varscan2
- ALG1L | c.184C>T p.L62= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs113361787, COSV100444885; called by muse, mutect2, varscan2
- AMIGO2 | c.153C>T p.I51= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs1438385044, COSV56974219, COSV56975561; called by muse, mutect2, varscan2
- AMIGO3 | c.990G>A p.A330= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV57539060; called by muse, mutect2, varscan2
- ANK2 | c.11787C>T p.N3929= | Silent (SNP) | VAF 49/87 reads (56%) | catalogued as COSV52169510; called by muse, mutect2, varscan2
- ANKRD50 | c.534G>A p.L178= | Silent (SNP) | VAF 49/77 reads (64%) | catalogued as COSV72385816; called by muse, mutect2, varscan2
- AOPEP | c.225G>A p.G75= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as COSV52919632; called by muse, mutect2, varscan2
- AP1B1 | c.1410C>T p.L470= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs757043271, COSV58015506, COSV58019141; called by muse, varscan2
- APOA4 | c.787C>T p.L263= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as rs769553343, COSV63360624; called by muse, mutect2, varscan2
- APOBEC3D | c.702C>T p.T234= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV53327126; called by muse, mutect2, varscan2
- ARHGEF10 | c.3948G>A p.L1316= (on ENST00000398564; = p.L1291= on NM_014629.4) | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV50656427; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.783G>A p.V261= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV63437877, COSV63438297; called by muse, mutect2
- ART5 | c.738C>T p.L246= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as rs777909444, COSV63364763; called by muse, mutect2, varscan2
- ASH1L | c.7471C>T p.L2491= (on ENST00000368346 / NM_001366177.2; = p.L2486= on NM_018489.3) | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV64209756; called by muse, mutect2, varscan2
- ATP6V1C2 | c.969C>T p.P323= (on ENST00000272238 / NM_001039362.2; = p.P277= on NM_144583.4) | Silent (SNP) | VAF 43/66 reads (65%) | catalogued as rs776621293, COSV55351616; called by muse, mutect2, varscan2
- AUTS2 | c.1788C>T p.P596= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as COSV61391334; called by muse, mutect2
- BMP6 | c.267C>T p.L89= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV51667478; called by muse, mutect2, varscan2
- C18orf54 | c.945G>A p.K315= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV55618545; called by muse, mutect2, varscan2
- C2CD3 | c.4045C>T p.L1349= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV58094681; called by muse, mutect2, varscan2
- C5 | c.4044C>T p.V1348= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs139210706; called by muse, mutect2, varscan2
- CA11 | c.351C>T p.V117= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV50033367; called by muse, mutect2, varscan2
- CACNA1B | c.2397C>T p.F799= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs1240555317, COSV99499098; called by muse, mutect2, varscan2
- CADPS | c.2961G>A p.L987= | Silent (SNP) | VAF 82/159 reads (52%) | catalogued as COSV51887420; called by muse, mutect2, varscan2
- CAPN9 | c.699C>T p.F233= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV55235569; called by muse, mutect2, varscan2
- CARMIL3 | c.141G>A p.L47= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV57727045; called by muse, mutect2, varscan2
- CBR1 | c.708G>A p.A236= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs368608178, COSV99289431; called by muse, mutect2, varscan2
- CCDC114 | c.681C>T p.L227= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV59557280; called by muse, mutect2, varscan2
- CCDC158 | c.324G>A p.L108= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as COSV66356435; called by muse, mutect2, varscan2
- CD2AP | c.1890G>A p.E630= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs1253535990, COSV63761391; called by muse, mutect2, varscan2
- CD3D | c.24T>C p.S8= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV52675309; called by muse, mutect2, varscan2
- CEACAM1 | c.604C>T p.L202= | Silent (SNP) | VAF 95/259 reads (37%) | catalogued as rs1274317654, COSV50728669; called by muse, mutect2, varscan2
- CLIC1 | c.33C>T p.F11= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs200422429, COSV65210215, COSV65210450; called by muse, mutect2, varscan2
- CLN5 | c.36G>A p.E12= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs779057868, COSV101080409; called by muse, varscan2
- CNDP2 | c.87G>A p.Q29= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV60840385; called by muse, mutect2, varscan2
- COL25A1 | c.177C>G p.L59= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV67652333; called by muse, mutect2, varscan2
- CRTAP | c.468C>T p.F156= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as rs1341066591, COSV100310167; called by muse, mutect2, varscan2
- CTDSP2 | c.738G>A p.L246= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV101142987, COSV66079994; called by muse, mutect2, varscan2
- CYP27B1 | c.915G>A p.Q305= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV56985576; called by muse, mutect2, varscan2
- CYTIP | c.822C>T p.F274= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as rs764199968, COSV51634363; called by muse, mutect2, varscan2
- DCAF12L1 | c.39G>A p.A13= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100948300, COSV64422066; called by muse, mutect2, varscan2
- DCP1B | c.1635C>T p.L545= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV54970186; called by muse, mutect2, varscan2
- DCST2 | c.885C>G p.L295= | Silent (SNP) | VAF 39/56 reads (70%) | catalogued as COSV55052503; called by muse, mutect2, varscan2
- DENND4B | c.3414C>T p.L1138= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as COSV63410102; called by muse, mutect2, varscan2
- DLEC1 | c.1902G>C p.L634= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as COSV57301706; called by muse, mutect2
- DLGAP1 | c.2802G>A p.E934= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100233058; called by muse, mutect2
- DNAAF2 | c.2499A>T p.L833= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV53566502; called by muse, mutect2, varscan2
- DNAJC6 | c.543C>T p.F181= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV54777209; called by muse, mutect2, varscan2
- DOCK5 | c.2658C>T p.L886= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV52404693, COSV99376081; called by muse, mutect2, varscan2
- DSP | c.1620C>T p.L540= | Silent (SNP) | VAF 89/136 reads (65%) | catalogued as COSV65793586; called by muse, mutect2, varscan2
- DST | c.1452C>T p.Y484= (on ENST00000361203 / NM_001374722.1; = p.Y158= on NM_001723.6) | Silent (SNP) | VAF 64/108 reads (59%) | catalogued as rs1563391806, COSV55022898; called by muse, mutect2, varscan2
- DUSP22 | c.42C>T p.I14= | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as rs762921083, COSV60528266; called by muse, mutect2, varscan2
- DYNC1H1 | c.10221G>A p.K3407= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV64138487; called by muse, mutect2, varscan2
- EBLN2 | c.504C>T p.F168= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs764474856, COSV55596437; called by muse, mutect2, varscan2
- EFHD1 | c.387G>T p.L129= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV51133147; called by muse, mutect2, varscan2
- ERBB2 | c.2370G>A p.L790= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV54074081; called by muse, mutect2, varscan2
- ERMP1 | c.624A>G p.S208= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs768978196, COSV53038064; called by muse, mutect2, varscan2
- FASN | c.5403C>T p.N1801= | Silent (SNP) | VAF 43/54 reads (80%) | catalogued as rs775171713, COSV60756844; called by muse, mutect2, varscan2
- FAT4 | c.11557C>T p.L3853= | Silent (SNP) | VAF 48/72 reads (67%) | catalogued as COSV58692533; called by muse, mutect2, varscan2
- FBXO32 | c.60C>T p.D20= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs568106989, COSV71552198; called by muse, mutect2, varscan2
- FLG2 | c.4380A>T p.T1460= | Silent (SNP) | VAF 437/617 reads (71%) | catalogued as COSV66169783; called by muse, mutect2, varscan2
- FLOT2 | c.1200C>G p.A400= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV101204795, COSV67529097; called by muse, mutect2
- FNBP4 | c.2340C>T p.I780= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV55449776, COSV99771980; called by muse, mutect2, varscan2
- G3BP2 | c.648G>A p.K216= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as COSV62975742, COSV62976727; called by muse, mutect2, varscan2
- GCN1 | c.7548T>C p.S2516= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV56109962; called by muse, mutect2, varscan2
- GDF7 | c.1179C>T p.T393= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV55348018; called by muse, mutect2, varscan2
- GGT7 | c.1416G>A p.T472= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs145189899; called by muse, mutect2, varscan2
- GIT2 | c.111C>T p.V37= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV58082304; called by muse, mutect2, varscan2
- GPR1 | c.321C>T p.I107= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as COSV67977038; called by muse, mutect2, varscan2
- H2AC4 | c.250C>T p.L84= | Silent (SNP) | VAF 11/241 reads (5%) | catalogued as rs1429374780, COSV52519110; called by muse, mutect2
- H4C11 | c.246C>T p.V82= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV100747931, COSV100748007; called by muse, mutect2, varscan2
- HDAC3 | c.627C>A p.V209= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV59496468; called by muse, mutect2, varscan2
- HID1 | c.1878G>A p.L626= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV59351795; called by muse, mutect2, varscan2
- HPS1 | c.1057C>T p.L353= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs200850713, COSV57268640; called by muse, mutect2, varscan2
- HRAS | c.564C>T p.L188= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99530282, COSV99530681; called by muse, mutect2
- HSD17B10 | c.213G>A p.V71= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV51448300; called by muse, mutect2, varscan2
- HSF2 | c.186G>A p.V62= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV63774110; called by muse, mutect2, varscan2
- HSF5 | c.804A>C p.T268= | Silent (SNP) | VAF 122/165 reads (74%) | catalogued as COSV60417637; called by muse, mutect2, varscan2
- HSPA8 | c.1926T>C p.I642= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV57084484; called by muse, mutect2, varscan2
- IDE | c.676C>T p.L226= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as COSV56423384, COSV56424712; called by muse, mutect2
- IGSF22 | c.1314G>T p.L438= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV60035652; called by muse, mutect2, varscan2
- IHH | c.342G>A p.L114= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as COSV55393064, COSV55393482; called by muse, mutect2, varscan2
- IL16 | c.1884C>T p.T628= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV57264967; called by muse, mutect2, varscan2
- IL17RB | c.931C>T p.L311= | Silent (SNP) | VAF 51/111 reads (46%) | catalogued as COSV55471838, COSV55473420; called by muse, mutect2, varscan2
- INTS6L | c.1683G>A p.L561= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV66084876; called by muse, mutect2, varscan2
- IRAK1 | c.348G>A p.P116= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV57654923; called by muse, mutect2
- IRS4 | c.762C>T p.F254= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV64534442; called by muse, mutect2, varscan2
- ISLR2 | c.1854T>C p.A618= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV62302590; called by muse, mutect2, varscan2
- JCAD | c.3312G>A p.R1104= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV64760361; called by muse, mutect2, varscan2
- KCNK13 | c.1113C>T p.A371= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56413883; called by muse, mutect2, varscan2
- KCNT2 | c.3132C>T p.Y1044= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV54088056; called by muse, mutect2, varscan2
- KCTD3 | c.1077G>A p.L359= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV52067949; called by muse, mutect2, varscan2
- KIF22 | c.1740C>T p.I580= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs1434924288, COSV50716159; called by muse, mutect2, varscan2
- KIF3B | c.1761A>C p.I587= | Silent (SNP) | VAF 65/128 reads (51%) | catalogued as COSV65228130; called by muse, mutect2, varscan2
- KNDC1 | c.3708C>T p.N1236= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs147343928, COSV58840349; called by muse, mutect2, varscan2
- KRT76 | c.1393C>T p.L465= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV60120794; called by muse, mutect2, varscan2
- LAG3 | c.1455C>T p.A485= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1376880966, COSV99179993; called by muse, varscan2
- LENG8 | c.153G>A p.K51= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV58728671; called by muse, mutect2, varscan2
- LIMCH1 | c.361A>C p.R121= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV58287634; called by muse, mutect2, varscan2
- LRRC37B | c.1659C>T p.Y553= | Silent (SNP) | VAF 34/221 reads (15%) | catalogued as COSV58953024; called by muse, mutect2, varscan2
- LRRIQ4 | c.906G>C p.L302= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV61619491; called by muse, mutect2, varscan2
- LRRN4 | c.1884C>T p.V628= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1251216977, COSV66645846; called by muse, mutect2, varscan2
- LVRN | c.384T>G p.T128= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV63497580; called by muse, mutect2, varscan2
- MAN2B2 | c.198C>T p.R66= | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as rs779997292, COSV53454200; called by muse, mutect2, varscan2
- MARCHF10 | c.2121C>T p.A707= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100248503; called by muse, mutect2
- MDN1 | c.6102G>A p.P2034= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs377455110, COSV65523909; called by muse, mutect2, varscan2
- MEI1 | c.3687G>A p.L1229= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV55388297; called by muse, mutect2, varscan2
- MEIS1 | c.117G>A p.L39= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV55488555; called by muse, mutect2, varscan2
- MPP6 | c.1095A>G p.R365= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1046827630, COSV56039852; called by muse, mutect2, varscan2
- MROH1 | c.3051C>T p.L1017= | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as rs1398502063; called by muse, mutect2, varscan2
- NAALAD2 | c.228A>G p.T76= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV58962376; called by muse, mutect2, varscan2
- NAGA | c.624C>T p.I208= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV101124136, COSV67170045; called by muse, mutect2, varscan2
- NARS2 | c.105G>A p.G35= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV55252939; called by muse, mutect2, varscan2
- NF2 | c.651C>T p.Y217= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs367802186, COSV99052164; called by muse, mutect2, varscan2
- NRM | c.612G>A p.L204= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV51296839; called by muse, mutect2, varscan2
- NSD1 | c.4272C>G p.P1424= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs764484130, COSV61778465; called by muse, mutect2, varscan2
- OPHN1 | c.1182C>A p.I394= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV62782464, COSV62783446, COSV62784904; called by muse, mutect2, varscan2
- OPN3 | c.138G>A p.L46= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV59365357; called by muse, mutect2, varscan2
- OR1I1 | c.360C>T p.I120= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs370613854; called by muse, mutect2, varscan2
- OR1J2 | c.246G>A p.L82= | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as COSV58944607; called by muse, mutect2, varscan2
- OR2Z1 | c.618C>T p.I206= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV60692728; called by muse, mutect2, varscan2
- OR3A3 | c.891T>G p.L297= | Silent (SNP) | VAF 45/84 reads (54%) | catalogued as COSV52167802; called by muse, mutect2, varscan2
- OR8U1 | c.678G>C p.L226= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs375217170; called by muse, mutect2, varscan2
- ORMDL2 | c.306C>T p.L102= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as rs766211372, COSV54478737; called by muse, mutect2, varscan2
- OSTM1 | c.333C>T p.L111= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs767465528, COSV51970373; called by muse, varscan2
- PALB2 | c.1272C>G p.A424= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as rs754720030, COSV55166609; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAQR7 | c.147G>A p.A49= | Silent (SNP) | VAF 45/82 reads (55%) | catalogued as rs779379788, COSV65351906; called by muse, mutect2, varscan2
- PATZ1 | c.490C>T p.L164= | Silent (SNP) | VAF 67/166 reads (40%) | catalogued as rs747817525, COSV53229950; called by muse, mutect2, varscan2
- PCNT | c.1314C>T p.F438= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV64029849; called by muse, mutect2, varscan2
- PCNX3 | c.4020C>T p.L1340= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs777616571, COSV63137900; called by muse, mutect2, varscan2
- PCSK7 | c.1281G>A p.T427= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs781668391, COSV58007999; called by muse, mutect2, varscan2
- PDCD11 | c.5115G>A p.E1705= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV53296373; called by muse, mutect2, varscan2
- PDK3 | c.24G>A p.L8= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV64793717; called by muse, mutect2, varscan2
- PELO | c.639G>A p.V213= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV50885822; called by muse, mutect2, varscan2
- PIF1 | c.810C>T p.A270= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV51422921; called by muse, mutect2, varscan2
- PIK3AP1 | c.1791T>C p.F597= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV59533970; called by muse, mutect2
123 further variants in this file (0 protein-altering or splice-affecting, 101 silent, 22 other) are not listed here.
